Somatic mutation profile of tumor specimen 1105257 (aliquot 7316UP-349-1105257) from CPTAC case C259161, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Brain, NOS; Tumor grade: G4.
Specimen 1105257: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1733eb8-ec4c-4fae-b379-7d61d5cb163c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105283 (Blood Derived Normal), aliquot 7316UP-293-1105283; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40fb28ad-b511-4d0f-9d64-9d9365ba9044

The open-access MAF lists 133 somatic variants for this specimen: 94 protein-altering or splice-affecting, 21 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 21, Intron 8, Nonsense Mutation 7, RNA 7, Splice Region 3, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 117/157 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 613/743 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASAP3 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 168/468 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs148195646; called by muse, mutect2, varscan2
- BRCA2 | c.7386del p.N2463Ifs*4 | Frame Shift Del (DEL) | VAF 84/139 reads (60%) | catalogued as COSV66464724; called by mutect2, pindel, varscan2
- CAPS | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 103/280 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs540490939; called by muse, mutect2, varscan2
- CDC14C | c.1125A>T p.R375S (on ENST00000428251; = p.R268S on NM_152627.3) | Missense Mutation (SNP) | VAF 139/664 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs755866926; called by muse, mutect2, varscan2
- CDH18 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1434063547, COSV56927210, COSV99931214; called by muse, mutect2, varscan2
- CEL | c.1796C>T p.T599M (on ENST00000673714; = p.T596M on NM_001807.6) | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.855); catalogued as rs1267029539; called by muse, varscan2
- CFAP206 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs377549577, COSV51535435; called by muse, mutect2, varscan2
- CLCA4 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs374250322; called by muse, varscan2
- CR2 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 78/270 reads (29%) | catalogued as rs1161576814, COSV65510786; called by muse, mutect2, varscan2
- CUX2 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 162/448 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs1225937198, COSV55648814; called by muse, varscan2
- DNAH12 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs534723794; called by muse, mutect2, varscan2
- EPHA8 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1394031937, COSV51263170; called by muse, mutect2, varscan2
- FARSA | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs868440760; called by muse, mutect2, varscan2
- FZD5 | c.1640G>C p.S547T | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.072); catalogued as rs768166154; called by muse, mutect2, varscan2
- GASK1B | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as rs201221389, COSV56709157; called by muse, mutect2, varscan2
- GYG2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 97/124 reads (78%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs767686645; called by muse, mutect2, varscan2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- IL4R | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs372988882; called by muse, mutect2, varscan2
- KCNU1 | c.2473G>A p.G825R | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs372670243; called by muse, mutect2, varscan2
- LONRF1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs747682337; called by muse, mutect2, varscan2
- MMP13 | c.1325A>G p.Y442C | Missense Mutation (SNP) | VAF 122/286 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781952022; called by muse, mutect2, varscan2
- PLCB4 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 99/287 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.854); catalogued as rs144345083; ClinVar: benign; called by muse, mutect2, varscan2
- PLEKHN1 | c.276C>A p.N92K | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs755479010; called by muse, mutect2, varscan2
- PROP1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 768/1141 reads (67%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs372313496; called by muse, mutect2, varscan2
- PTDSS1 | c.1017C>A p.Y339* | Nonsense Mutation (SNP) | VAF 85/199 reads (43%) | catalogued as COSV61264462; called by muse, mutect2, varscan2
- RSPH1 | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs376824155; called by muse, mutect2, varscan2
- SCN3A | c.5611C>T p.R1871* | Nonsense Mutation (SNP) | VAF 17/572 reads (3%) | catalogued as rs1193842951, COSV51801338; called by muse, mutect2
- SCN3A | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 133/288 reads (46%) | catalogued as COSV51820116; called by muse, mutect2, varscan2
- SCN7A | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs959540957; called by muse, mutect2, varscan2
- SPAM1 | c.101T>C p.L34S | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as rs1258146565; called by muse, mutect2, varscan2
- STK31 | c.2786A>C p.E929A | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV63455470; called by muse, mutect2, varscan2
- TAF2 | c.1157T>C p.F386S | Missense Mutation (SNP) | VAF 140/357 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754007710; called by muse, mutect2, varscan2
- TBC1D28 | c.198+8C>T | Splice Region (SNP) | VAF 15/59 reads (25%) | catalogued as rs781038525; called by muse, mutect2, varscan2
- TBX3 | c.806G>A p.R269Q (on ENST00000257566 / NM_016569.4; = p.R249Q on NM_005996.4) | Missense Mutation (SNP) | VAF 165/428 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs775378442, COSV57469287; called by muse, mutect2, varscan2
- TMEM104 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.329); catalogued as COSV59108050; called by muse, mutect2
- WDSUB1 | c.400T>C p.C134R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as rs750682609; called by muse, mutect2, varscan2
- ZNF230 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 123/183 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV71273615; called by muse, mutect2, varscan2
- AADAC | c.1129T>A p.S377T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.057); called by muse, mutect2
- ACBD4 | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAM11 | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 124/152 reads (82%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- ARAP2 | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARHGEF33 | c.2098G>C p.G700R | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRF1 | c.2006G>A p.C669Y | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.979); called by muse, mutect2
- CADM3 | c.340A>T p.T114S (on ENST00000368125 / NM_001127173.3; = p.T148S on NM_021189.5) | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC25B | c.56T>A p.V19E | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CDX4 | c.746A>T p.D249V | Missense Mutation (SNP) | VAF 78/107 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLP1 | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.05); called by muse, mutect2
- DDX3X | c.839A>T p.Q280L (on ENST00000399959; = p.Q281L on NM_001356.5) | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNALI1 | c.29_41del p.G10Afs*10 | Frame Shift Del (DEL) | VAF 98/278 reads (35%) | called by mutect2, pindel, varscan2
- DOCK8 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 118/171 reads (69%) | called by muse, mutect2, varscan2
- DOCK8 | c.2102C>G p.S701C | Missense Mutation (SNP) | VAF 148/223 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- DOCK8 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 114/153 reads (75%) | called by muse, mutect2, varscan2
- DYNAP | c.264T>A p.H88Q (on ENST00000321600; = p.H62Q on NM_173629.3) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- EGR4 | c.1022C>A p.T341N (on ENST00000545030; = p.T238N on NM_001965.4) | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FLNB | c.2680A>G p.K894E | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GALNT18 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 97/142 reads (68%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- HMCN1 | c.2441_2443del p.C814del | In Frame Del (DEL) | VAF 104/279 reads (37%) | called by mutect2, pindel, varscan2
- HOXA3 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXD3 | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL1RAPL2 | c.900A>T p.I300= | Splice Region (SNP) | VAF 29/33 reads (88%) | called by muse, mutect2, varscan2
- ITGA11 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ITGA6 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 242/629 reads (38%) | SIFT tolerated (0.79); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ13 | c.730dup p.Y244Lfs*17 | Frame Shift Ins (INS) | VAF 61/209 reads (29%) | called by mutect2, pindel, varscan2
- KCNT1 | c.2566A>G p.I856V (on ENST00000488444; = p.I875V on NM_020822.3) | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KIF18A | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMC3 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 52/606 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LMBRD2 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MINDY2 | c.968T>G p.M323R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- NAV3 | c.6721C>T p.R2241* (on ENST00000397909 / NM_001024383.2; = p.R2219* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- NEURL1 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.085); called by muse, mutect2
- NOTCH4 | c.3328T>A p.F1110I | Missense Mutation (SNP) | VAF 118/252 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE6A | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 25/366 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2
- PDLIM3 | c.8A>C p.Q3P | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PLP2 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 200/242 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PTTG1 | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 44/505 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- RAB3GAP1 | c.2290-6C>T | Splice Region (SNP) | VAF 11/316 reads (3%) | called by muse, mutect2
- RASD2 | c.39T>A p.S13R | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASGRP4 | c.395A>T p.H132L | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLC27A2 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 123/309 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SLC7A14 | c.2186T>C p.F729S | Missense Mutation (SNP) | VAF 94/438 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- STYXL2 | c.1909C>G p.L637V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TCTN2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 161/281 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TENM4 | c.8177A>T p.Q2726L | Missense Mutation (SNP) | VAF 133/312 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TG | c.1783T>G p.L595V | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TKTL2 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 53/240 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM181 | c.518T>G p.I173S | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- TMEM187 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 247/299 reads (83%) | SIFT tolerated (0.14); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- TNFRSF11A | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TPBG | c.1070T>A p.V357D | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRAV16 | c.317G>C p.C106S | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- UGT3A2 | c.933A>T p.E311D | Missense Mutation (SNP) | VAF 131/384 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ZRANB3 | c.2899C>T p.L967F | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADAT3 | c.750C>T p.R250= | Silent (SNP) | VAF 140/332 reads (42%) | catalogued as rs767225266, COSV100280462; called by muse, mutect2, varscan2
- AHNAK | c.8052A>G p.E2684= | Silent (SNP) | VAF 173/441 reads (39%) | called by muse, mutect2, varscan2
- CDH1 | c.1095C>G p.V365= | Silent (SNP) | VAF 173/483 reads (36%) | called by muse, mutect2, varscan2
- CEACAM5 | c.1827G>A p.A609= | Silent (SNP) | VAF 151/207 reads (73%) | catalogued as rs782555811, COSV55752088; called by muse, mutect2, varscan2
- CNR2 | c.726G>A p.R242= | Silent (SNP) | VAF 52/129 reads (40%) | called by muse, mutect2
- FLNB | c.1260C>A p.P420= | Silent (SNP) | VAF 16/376 reads (4%) | called by muse, mutect2
- FLNB | c.4284C>A p.G1428= | Silent (SNP) | VAF 81/325 reads (25%) | called by muse, mutect2, varscan2
- FOXL2 | c.648C>G p.A216= | Silent (SNP) | VAF 102/231 reads (44%) | called by muse, mutect2, varscan2
- GRIA1 | c.2079A>G p.P693= | Silent (SNP) | VAF 109/272 reads (40%) | called by muse, mutect2, varscan2
- GRIP2 | c.879C>T p.G293= (on ENST00000619221; = p.G196= on NM_001080423.4) | Silent (SNP) | VAF 90/188 reads (48%) | catalogued as rs774000698, COSV56121182; called by muse, mutect2, varscan2
- KTN1 | c.3636A>G p.E1212= (on ENST00000395314 / NM_001271014.2; = p.E1183= on NM_004986.4) | Silent (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- MEFV | c.630G>C p.A210= | Silent (SNP) | VAF 96/245 reads (39%) | catalogued as rs770830323, COSV54819142; called by muse, mutect2, varscan2
- MMP10 | c.1176T>C p.S392= | Silent (SNP) | VAF 51/143 reads (36%) | called by muse, mutect2, varscan2
- NECAB2 | c.501C>T p.R167= | Silent (SNP) | VAF 63/167 reads (38%) | catalogued as rs755827646, COSV100534184; called by muse, mutect2, varscan2
- PCDHB12 | c.1398C>A p.P466= | Silent (SNP) | VAF 337/822 reads (41%) | catalogued as COSV53398333; called by muse, mutect2, varscan2
- RAG1 | c.2865C>T p.S955= | Silent (SNP) | VAF 210/506 reads (42%) | catalogued as COSV55025939; called by muse, mutect2, varscan2
- SALL1 | c.1665C>T p.V555= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as rs201565524, COSV51757309; called by muse, mutect2, varscan2
- SDC4 | c.27G>T p.L9= | Silent (SNP) | VAF 147/291 reads (51%) | called by muse, mutect2, varscan2
- SLC25A22 | c.732C>T p.N244= | Silent (SNP) | VAF 308/419 reads (74%) | called by muse, mutect2, varscan2
- STK10 | c.2244G>A p.E748= | Silent (SNP) | VAF 123/414 reads (30%) | called by muse, mutect2, varscan2
- ZNF285 | c.1050G>A p.G350= | Silent (SNP) | VAF 107/142 reads (75%) | catalogued as rs1417500744; called by muse, mutect2, varscan2
- AC073348.1 | n.171T>A | RNA (SNP) | VAF 73/158 reads (46%) | called by muse, mutect2, varscan2
- ANKRD42 | c.*61T>C | 3'UTR (SNP) | VAF 111/264 reads (42%) | called by muse, mutect2, varscan2
- CPEB2 | chr4:15001972 T>C | 5'Flank (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2
- DCHS2 | n.4989G>C | RNA (SNP) | VAF 98/229 reads (43%) | called by muse, mutect2, varscan2
- DOCK8 | c.1797+143C>T | Intron (SNP) | VAF 75/112 reads (67%) | called by muse, mutect2, varscan2
- F13A1 | c.1113-9236G>A | Intron (SNP) | VAF 71/98 reads (72%) | catalogued as rs375862509; called by muse, mutect2, varscan2
- FER1L4 | n.4463A>C | RNA (SNP) | VAF 19/367 reads (5%) | called by muse, mutect2
- GALM | c.346-1214G>A | Intron (SNP) | VAF 62/166 reads (37%) | called by muse, mutect2, varscan2
- HERC2P4 | n.155G>A | RNA (SNP) | VAF 193/484 reads (40%) | called by muse, mutect2, varscan2
- MS4A2 | c.538-48C>T | Intron (SNP) | VAF 109/265 reads (41%) | catalogued as rs751308080, COSV54012029; called by muse, mutect2, varscan2
- MYO16 | c.-39+33573_-39+33585del | Intron (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- ROGDI | c.117+238G>A | Intron (SNP) | VAF 43/123 reads (35%) | called by muse, mutect2, varscan2
- RPAIN | c.-3G>A | 5'UTR (SNP) | VAF 167/459 reads (36%) | called by muse, mutect2, varscan2
- SEZ6 | c.1576+51_1576+78del | Intron (DEL) | VAF 36/152 reads (24%) | called by mutect2, pindel
- SSPOP | n.14771C>T | RNA (SNP) | VAF 20/50 reads (40%) | catalogued as rs370703581; called by muse, mutect2, varscan2
- TMEM185AP1 | n.112C>T | RNA (SNP) | VAF 16/21 reads (76%) | catalogued as rs1316740917; called by mutect2, varscan2
- UGT2B27P | n.1491G>T | RNA (SNP) | VAF 290/570 reads (51%) | called by muse, mutect2, varscan2
- VWA3B | c.2673+5532C>G | Intron (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
